Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A240, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A240-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-0-3

dedifferentiated liposarcoma 8858/3
Site (other) spermatic cord C63.1
hw 4/24/11

Clinical Diagnosis & History:

51 y/o male with left inguinal mass; positive for spindle cell sarcoma.

Specimens Submitted:

1: SP: Spermatic cord liposarcoma with testis

DIAGNOSIS:

- 1) SOFT TISSUE, SPERMATIC CORD AND TESTIS; EXCISION:
- DEDIFFERENTIATED LIPOSARCOMA.
- WELL DIFFERENTIATED COMPONENT (SCLEROSING SUBTYPE) MAKES UP LESS THAN 10% OF THE TUMOR; NONLIPOGENIC ELEMENT HAS THE APPEARANCE OF A LOW GRADE SPINDLE CELL SARCOMA WITH HIGH MITOTIC RATE BUT NO PLEOMORPHISM OR NECROSIS.
- TUMOR MEASURES 13.5 CM GREATEST DIMENSION, INVOLVES FIBROADIPOSE TISSUE INCLUDING SPERMATIC CORD, AND ABUTS VAS DEFERENS (TESTIS IS NOT INVOLVED BY TUMOR).
- TUMOR IS 0.08 CM FROM AN UNDESIGNATED INKED MARGIN.
- CUTANEOUS SCAR; SYNTHETIC MESH WITH ASSOCIATED FOREIGN BODY REACTION.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

, M.D.

1.) The specimen is received fresh, labeled "spermatic cord liposarcoma with testis", and consists of a small ellipse of tan skin with underlying subcutaneous tissue and mass with attached testicle. The skin ellipse measures 10.3 x 1.1 cm and contains a 5.1 cm elongated scar. There is a large ovoid firm mass present in subcutaneous tissues measuring 13.5 x 6.1 x 5.5 cm. The mass appears to be completely covered by pink-tan delicate pseudocapsule. Serial sectioning through the mass reveals lobulated homogeneous white tan whorled cut surfaces with focal hemorrhage. No

** Continued on next page **

[page 2 of 2]
----- Page 2 of 2
necrosis is identified. Attached to the mass is a synthetic mesh measuring 6.0 x 3.0 x 0.3 cm, which is partially surrounded by the tumor. The testicle is present measuring 5.5 x 4.0 x 3.0 cm. There is a hydrocele containing approximately 10 ml of clear fluid. Serial sectioning through the testicle reveals unremarkable tan-brown parenchyma. The attached vas deferens measures 6.5 cm in length and average diameter of 0.3 cm and is involved by the tumor at the proximal end. Representative sections are submitted. Portions of the specimen are submitted for TPS. The specimen photographs are taken.

Summary of sections:

M -- margin
T -- tumor
TEST -- testicle
SCT vas deferens with tumor
SS -- skin with scar
ADDT additional sections of tumor

Summary of Sections:

Part 1: SP: Spermatic cord liposarcoma with testis

Block	Sect.	Site	PCs	
8		ADDT		8
2		M	2	
1		SCT		1
1		SS	1	
8		T	8	
1		TEST		1

** End of Report **

Source: NCI Genomic Data Commons file 3f1f426a-8da9-4830-a093-8835a9ff5cdf (TCGA-DX-A240.40282FEF-F7D1-44AF-ABA6-C76A86FEE518.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).